Somatic mutation profile of tumor specimen MP2PRT-PASVLF-TMP1-A (aliquot MP2PRT-PASVLF-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,764 days).
Specimen MP2PRT-PASVLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f07758e-e1d0-4fe2-8238-2dd01abc42de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVLF-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf936432-e657-4fca-9774-25dd5bb9acc4

The open-access MAF lists 110 somatic variants for this specimen: 78 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 27, Nonsense Mutation 10, Intron 4, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 20/358 reads (6%) | catalogued as COSV99256848; called by muse, mutect2
- ADAMTS20 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 17/487 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1039380050; called by muse, mutect2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2
- ANKRD50 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 107/439 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs751442384; called by muse, mutect2, varscan2
- ATM | c.8683G>C p.E2895Q | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53734559, COSV99069695; called by muse, mutect2, varscan2
- BEND6 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66069843; called by muse, mutect2, varscan2
- CABP1 | c.898G>C p.D300H (on ENST00000316803 / NM_001033677.1; = p.D97H on NM_004276.5) | Missense Mutation (SNP) | VAF 103/464 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as COSV99974704; called by muse, mutect2, varscan2
- CASD1 | c.968C>G p.S323C | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV51973034; called by muse, mutect2, varscan2
- CBLN2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV54050194, COSV54053259; called by muse, mutect2, varscan2
- CDH12 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66397834; called by muse, mutect2
- CH25H | c.673C>G p.H225D | Missense Mutation (SNP) | VAF 110/413 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV64092465; called by muse, mutect2, varscan2
- CHL1 | c.2862G>C p.Q954H (on ENST00000397491 / NM_001253387.1; = p.Q970H on NM_006614.4) | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.645); catalogued as COSV56605086; called by muse, mutect2
- CNTN3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV55178720; called by muse, mutect2, varscan2
- CNTN4 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV61881652; called by muse, mutect2
- COL3A1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 104/426 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58582150; called by muse, mutect2, varscan2
- DNTTIP1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 97/399 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1358842419; called by muse, mutect2, varscan2
- EFCAB6 | c.4308G>A p.W1436* | Nonsense Mutation (SNP) | VAF 31/503 reads (6%) | catalogued as rs753309592; called by muse, mutect2
- GRIA2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 11/354 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.424); catalogued as COSV52398270; called by muse, mutect2
- INSYN1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1312640368, COSV65837233; called by muse, mutect2, varscan2
- IZUMO3 | c.664G>A p.E222K (on ENST00000543880 / NM_001365008.2; = p.E216K on NM_001271706.1) | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV69048284; called by muse, mutect2, varscan2
- MAP7 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485751656, COSV100643778; called by muse, mutect2
- MSANTD1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 41/744 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1359123623, COSV70873277; called by muse, mutect2
- OR4C13 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs563481475; called by muse, mutect2
- PCDH15 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57317010; called by muse, mutect2, varscan2
- PDE1C | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1225158489, COSV58512683, COSV58526556; called by muse, mutect2
- PGK2 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 105/425 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59165245; called by muse, mutect2, varscan2
- POLR2B | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 51/304 reads (17%) | catalogued as COSV58902272; called by muse, mutect2, varscan2
- SHISA6 | c.816C>A p.N272K (on ENST00000409168 / NM_001173461.1; = p.N323K on NM_207386.4) | Missense Mutation (SNP) | VAF 99/410 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs555548608; called by muse, mutect2, varscan2
- TAF1 | c.3286C>T p.Q1096* (on ENST00000373790 / NM_138923.4; = p.Q1117* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/539 reads (4%) | catalogued as COSV99336831; called by muse, mutect2
- TBX5 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV100091732, COSV59862447; called by muse, mutect2, varscan2
- TENM1 | c.3796C>G p.L1266V | Missense Mutation (SNP) | VAF 115/400 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV64426134; called by muse, varscan2
- TMEM158 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV61528355; called by muse, mutect2, varscan2
- ZNF257 | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 13/300 reads (4%) | catalogued as COSV101448176, COSV71306330; called by muse, mutect2
- ZNF471 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs867394261; called by muse, mutect2, varscan2
- ZNF780A | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 26/507 reads (5%) | catalogued as rs1422989413; called by muse, mutect2
- ABHD3 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2
- ADGRV1 | c.8917G>A p.E2973K | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AGBL4 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AHI1 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AL592490.1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 19/523 reads (4%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.005); called by muse, mutect2
- APLP2 | c.1302C>G p.F434L | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP31 | c.3746A>G p.D1249G | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- BRINP3 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CACNA1G | c.2752C>G p.Q918E | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCSER2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPB | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 18/520 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- COBLL1 | c.3437C>G p.S1146C (on ENST00000392717; = p.S1108C on NM_014900.5) | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL5A2 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- DCDC2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMRT2 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- DNASE2B | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DPF2 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2
- DST | c.3491C>T p.S1164F (on ENST00000361203 / NM_001374722.1; = p.S838F on NM_001723.6) | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ECPAS | c.4640C>G p.S1547* | Nonsense Mutation (SNP) | VAF 96/441 reads (22%) | called by muse, mutect2, varscan2
- FGD6 | c.749G>C p.C250S | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- IGHV3-30 | chr14:106335080 TCTTTC>A | Missense Mutation (DEL) | VAF 56/62 reads (90%) | called by pindel, varscan2*
- KLHL1 | c.2058G>C p.L686F | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LHFPL3 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 88/321 reads (27%) | called by muse, varscan2
- ME2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR5A2 | c.653C>G p.S218C (on ENST00000367362 / NM_205860.3; = p.S172C on NM_003822.5) | Missense Mutation (SNP) | VAF 157/621 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDHB1 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 16/526 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RAPGEF2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- REL | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- SMG5 | c.2728G>T p.E910* | Nonsense Mutation (SNP) | VAF 58/285 reads (20%) | called by muse, varscan2
- SMIM23 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 90/432 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SSC4D | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 43/858 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2
- STYK1 | c.54C>T p.V18= | Splice Region (SNP) | VAF 15/261 reads (6%) | called by muse, mutect2
- TAF3 | c.2133G>C p.K711N | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TSPYL6 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 22/499 reads (4%) | called by muse, mutect2
- TSTD1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 83/404 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TYMS | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 126/573 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VSX2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 133/530 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY3 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 109/471 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 121/305 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF10 | c.1339C>A p.H447N | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2
- ZNF521 | c.3422C>G p.S1141C | Missense Mutation (SNP) | VAF 17/539 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF687 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 132/540 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNRF1 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACACB | c.6582G>T p.P2194= | Silent (SNP) | VAF 128/304 reads (42%) | catalogued as rs764874645, COSV58134536; called by muse, mutect2, varscan2
- ADAMTS1 | c.315G>A p.V105= | Silent (SNP) | VAF 17/624 reads (3%) | called by muse, mutect2
- ANKRD13A | c.855G>C p.L285= | Silent (SNP) | VAF 87/390 reads (22%) | called by muse, mutect2, varscan2
- ARNTL | c.510C>G p.L170= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, mutect2, varscan2
- BCL11B | c.807C>T p.L269= (on ENST00000357195 / NM_001282237.2; = p.L198= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/874 reads (5%) | catalogued as rs765063350; called by muse, mutect2
- CALB2 | c.537C>G p.L179= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as COSV56939738; called by muse, mutect2
- CNGA1 | c.1467G>A p.L489= | Silent (SNP) | VAF 23/566 reads (4%) | called by muse, mutect2
- EPHA6 | c.1233C>T p.F411= | Silent (SNP) | VAF 76/336 reads (23%) | catalogued as COSV67570526; called by muse, mutect2, varscan2
- GFI1B | c.633G>A p.T211= | Silent (SNP) | VAF 106/360 reads (29%) | catalogued as rs759546183, COSV100254437; called by muse, mutect2, varscan2
- H1-7 | c.699G>A p.K233= | Silent (SNP) | VAF 20/538 reads (4%) | catalogued as rs1317164117, COSV58602886; called by muse, mutect2
- HR | c.2637G>A p.R879= | Silent (SNP) | VAF 98/389 reads (25%) | called by muse, mutect2, varscan2
- HUWE1 | c.4731C>G p.V1577= | Silent (SNP) | VAF 59/285 reads (21%) | called by muse, mutect2, varscan2
- LRRC14B | c.417C>T p.A139= | Silent (SNP) | VAF 20/676 reads (3%) | called by muse, mutect2
- MACC1 | c.1356G>A p.R452= | Silent (SNP) | VAF 14/348 reads (4%) | catalogued as rs1228979740; called by muse, mutect2
- MICAL3 | c.5268C>T p.D1756= | Silent (SNP) | VAF 32/598 reads (5%) | catalogued as rs776449542; called by muse, mutect2
- NCAM1 | c.2136C>T p.N712= (on ENST00000316851 / NM_181351.5; = p.N702= on NM_000615.7) | Silent (SNP) | VAF 34/191 reads (18%) | catalogued as rs782293017; called by muse, mutect2, varscan2
- NLGN1 | c.21G>A p.T7= | Silent (SNP) | VAF 64/282 reads (23%) | catalogued as rs1346489280; called by muse, mutect2, varscan2
- NXT2 | c.141A>T p.I47= (on ENST00000372106 / NM_001242617.2; = p.I102= on NM_018698.5) | Silent (SNP) | VAF 138/375 reads (37%) | called by muse, mutect2, varscan2
- OBSCN | c.4452C>T p.F1484= | Silent (SNP) | VAF 111/391 reads (28%) | called by muse, mutect2, varscan2
- OR51G1 | c.414G>C p.L138= | Silent (SNP) | VAF 24/466 reads (5%) | called by muse, mutect2
- PSAPL1 | c.1062C>T p.I354= | Silent (SNP) | VAF 96/447 reads (21%) | catalogued as rs376334523; called by muse, mutect2, varscan2
- RBBP7 | c.510C>T p.L170= | Silent (SNP) | VAF 93/372 reads (25%) | called by muse, mutect2, varscan2
- SARDH | c.1158C>T p.F386= | Silent (SNP) | VAF 14/439 reads (3%) | called by muse, mutect2
- SHISAL1 | c.450G>T p.G150= | Silent (SNP) | VAF 160/618 reads (26%) | called by muse, mutect2, varscan2
- SLAMF9 | c.594C>T p.Y198= | Silent (SNP) | VAF 138/503 reads (27%) | called by muse, mutect2, varscan2
- TENT5A | c.543C>T p.L181= | Silent (SNP) | VAF 64/279 reads (23%) | catalogued as COSV60787945; called by muse, mutect2, varscan2
- VGLL1 | c.513C>T p.L171= | Silent (SNP) | VAF 27/738 reads (4%) | catalogued as COSV65703709; called by muse, mutect2
- AL353804.4 | chrX:73821481 G>A | 3'Flank (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- ATM | c.5762+1006G>C | Intron (SNP) | VAF 70/132 reads (53%) | called by muse, mutect2, varscan2
- METTL15 | c.271-47668C>T | Intron (SNP) | VAF 21/504 reads (4%) | called by muse, mutect2
- TTN | c.34265-3592G>C | Intron (SNP) | VAF 32/437 reads (7%) | catalogued as rs1359254201; called by muse, mutect2
- ZNF829 | c.320-355G>C | Intron (SNP) | VAF 68/285 reads (24%) | called by muse, mutect2, varscan2
